Somatic mutation profile of tumor specimen HCM-STAN-0840-C49-06A (aliquot HCM-STAN-0840-C49-06A-11D-A88H-36) from HCMI case HCM-STAN-0840-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Giant cell sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 67.4 years (24,606 days).
Specimen HCM-STAN-0840-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acfefc40-8a35-4948-87ca-caf0aca09d2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0840-C49-10A (Blood Derived Normal), aliquot HCM-STAN-0840-C49-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7148c6d7-6951-47c4-978e-2bdbc92bd197

The open-access MAF lists 105 somatic variants for this specimen: 77 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 26, Nonsense Mutation 9, Frame Shift Del 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MCCC2 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 34/199 reads (17%) | catalogued as rs763293192, COSV60157117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 68/989 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs752604368; called by muse, mutect2
- ADCY2 | c.1492T>G p.L498V | Missense Mutation (SNP) | VAF 97/535 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57884840; called by muse, mutect2, varscan2
- BARHL1 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 27/705 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as COSV55038547; called by muse, mutect2
- CFAP47 | c.1835C>G p.P612R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99935641; called by muse, varscan2
- DOCK8 | c.1053A>C p.K351N | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66634142; called by muse, mutect2
- FAM83C | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 134/742 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758395522; called by muse, mutect2, varscan2
- FANK1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 19/420 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV100904807; called by muse, mutect2
- HERC1 | c.14072G>A p.R4691Q | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757446033; called by muse, mutect2, varscan2
- HNF4G | c.614G>A p.R205H (on ENST00000354370 / NM_001330561.2; = p.R252H on NM_004133.5) | Missense Mutation (SNP) | VAF 192/312 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs767200428, COSV62967554, COSV62972655; called by muse, mutect2, varscan2
- IL1RAPL1 | c.929T>G p.L310R | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56247638; called by muse, mutect2
- KCNA4 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 227/396 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs777488025, COSV100068823; called by muse, mutect2, varscan2
- KLHL6 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 49/603 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375261661, COSV58064866; called by muse, mutect2
- KRTAP5-2 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 18/407 reads (4%) | PolyPhen benign (0.143); catalogued as rs369663200; called by muse, mutect2
- MASP1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 246/410 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs766084598, COSV51461074; called by muse, varscan2
- MRGPRF | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 307/622 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs866109625; called by muse, mutect2, varscan2
- NAA15 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 17/279 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56717890; called by muse, mutect2
- OR8K5 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 139/282 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756900844, COSV57889897, COSV57889909; called by muse, mutect2, varscan2
- PAX9 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 106/512 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.14); catalogued as COSV58730336; called by muse, mutect2, varscan2
- PSME4 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 30/207 reads (14%) | catalogued as COSV66368654; called by muse, mutect2, varscan2
- RAB11B | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 24/802 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1288425927; called by muse, mutect2
- SHKBP1 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 47/1152 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs762560064, COSV52543651; called by muse, mutect2
- SLC16A12 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 25/325 reads (8%) | catalogued as COSV57948115; called by muse, mutect2
- SLC37A1 | c.386A>T p.Y129F | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV61402468; called by muse, mutect2
- SYT6 | c.829C>T p.R277C (on ENST00000610222 / NM_001366225.1; = p.R192C on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 263/451 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs202111489; called by muse, mutect2, varscan2
- TDRD10 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 18/520 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs906755090, COSV52726257; called by muse, mutect2
- THSD7A | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 461/890 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70264148, COSV70268650; called by muse, mutect2, varscan2
- TP53 | c.999del p.R335Vfs*10 | Frame Shift Del (DEL) | VAF 179/395 reads (45%) | catalogued as COSV53129285; called by mutect2, pindel, varscan2
- TPCN1 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs779155395, COSV100136925; called by muse, mutect2
- TPM3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 141/271 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1407215498; called by muse, mutect2, varscan2
- WDR1 | c.1448G>T p.G483V (on ENST00000382452; = p.G343V on NM_005112.5) | Missense Mutation (SNP) | VAF 29/874 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as rs1241526381; called by muse, mutect2
- ZC3H18 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.189); catalogued as COSV56325368; called by muse, mutect2
- ZFHX4 | c.10160G>T p.S3387I | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs904313717; called by muse, mutect2
- ZNF100 | c.1454A>G p.Y485C | Missense Mutation (SNP) | VAF 121/378 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs1312668572; called by muse, mutect2, varscan2
- ZNF214 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs139112669; called by muse, mutect2, varscan2
- ZNF521 | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 46/460 reads (10%) | catalogued as COSV64125592, COSV99052392; called by muse, mutect2
- ADGRF4 | c.208T>A p.F70I | Missense Mutation (SNP) | VAF 159/298 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- AFF2 | c.3461A>C p.K1154T | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- BOD1L1 | c.4370T>G p.L1457R | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1QL4 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 44/888 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2
- CCSER1 | c.2618T>C p.L873S | Missense Mutation (SNP) | VAF 203/374 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLEC4D | c.542A>C p.N181T | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.196); called by muse, mutect2
- CSMD3 | c.8347T>C p.F2783L (on ENST00000297405 / NM_001363185.1; = p.F2614L on NM_052900.3) | Missense Mutation (SNP) | VAF 286/453 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CXCR3 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 26/837 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2
- CYP4B1 | c.476A>G p.E159G | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2
- DMBT1 | c.6886A>C p.T2296P (on ENST00000338354 / NM_001377530.1; = p.T1539P on NM_004406.3) | Missense Mutation (SNP) | VAF 29/602 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- DYSF | c.3247T>C p.Y1083H | Missense Mutation (SNP) | VAF 29/932 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.707); called by muse, mutect2
- FREM1 | c.6216A>C p.K2072N | Missense Mutation (SNP) | VAF 26/517 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.364); called by muse, mutect2
- GABRG3 | c.1315T>G p.L439V | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- GC | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- GNAO1 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPLD1 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- GRIA1 | c.2556A>C p.E852D | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- GRXCR1 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 271/547 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCY2C | c.1877T>C p.M626T | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2
- HAPLN4 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 36/1288 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2
- IGHV3OR15-7 | c.259G>C p.G87R | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KALRN | c.5826del p.D1943Tfs*14 (on ENST00000360013 / NM_001024660.4; = p.D246Tfs*14 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 132/303 reads (44%) | called by mutect2, pindel, varscan2
- MFAP3L | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 23/501 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MS4A8 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 17/528 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2
- OGFOD2 | c.484C>T p.Q162* (on ENST00000228922 / NM_001304833.1; = p.Q102* on NM_024623.3) | Nonsense Mutation (SNP) | VAF 200/316 reads (63%) | called by muse, varscan2
- OPLAH | c.86A>G p.H29R | Missense Mutation (SNP) | VAF 28/994 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- OR8H1 | c.289T>C p.F97L | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAQR9 | c.519C>G p.Y173* | Nonsense Mutation (SNP) | VAF 23/579 reads (4%) | called by muse, mutect2
- PARD3 | c.3496C>T p.Q1166* | Nonsense Mutation (SNP) | VAF 11/311 reads (4%) | called by muse, mutect2
- PARD3 | c.3495G>T p.K1165N | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2
- PMS1 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 180/305 reads (59%) | called by muse, mutect2, varscan2
- RHOJ | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 17/436 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2
- RPUSD3 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 21/355 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.125); called by muse, mutect2
- SCN8A | c.2172T>A p.Y724* | Nonsense Mutation (SNP) | VAF 13/349 reads (4%) | called by muse, mutect2
- SCRN2 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 22/598 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A5 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 23/695 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- SPTBN5 | c.9881A>C p.E3294A | Missense Mutation (SNP) | VAF 411/765 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SUPT6H | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 132/244 reads (54%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- TERF1 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 531/736 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, varscan2
- UTP3 | c.554G>T p.W185L | Missense Mutation (SNP) | VAF 247/445 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF782 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 27/360 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2
- ADAM18 | c.1743A>T p.I581= | Silent (SNP) | VAF 23/564 reads (4%) | called by muse, mutect2
- AHCYL2 | c.1794C>A p.L598= | Silent (SNP) | VAF 22/652 reads (3%) | called by muse, mutect2
- AMER3 | c.570G>A p.P190= | Silent (SNP) | VAF 302/566 reads (53%) | catalogued as rs1262658400, COSV58468055; called by muse, mutect2, varscan2
- BCKDHB | c.678G>A p.L226= | Silent (SNP) | VAF 77/152 reads (51%) | catalogued as COSV57519289; called by muse, mutect2, varscan2
- C6 | c.1074C>T p.F358= | Silent (SNP) | VAF 10/290 reads (3%) | catalogued as rs1325518197, COSV99667232; called by muse, mutect2
- CELSR1 | c.6678C>T p.N2226= | Silent (SNP) | VAF 433/781 reads (55%) | catalogued as rs776184322; called by muse, mutect2, varscan2
- CFAP46 | c.2217C>T p.N739= | Silent (SNP) | VAF 281/524 reads (54%) | catalogued as rs751927014, COSV63949636; called by muse, mutect2, varscan2
- COL25A1 | c.1269A>G p.Q423= | Silent (SNP) | VAF 16/502 reads (3%) | called by muse, mutect2
- DACT2 | c.756G>A p.P252= | Silent (SNP) | VAF 35/842 reads (4%) | catalogued as rs946069838; called by muse, mutect2
- DNAH10 | c.3777A>C p.A1259= (on ENST00000409039; = p.A1198= on NM_207437.3) | Silent (SNP) | VAF 33/312 reads (11%) | called by muse, mutect2, varscan2
- GNG13 | c.105G>A p.L35= | Silent (SNP) | VAF 24/355 reads (7%) | catalogued as rs760462519; called by muse, mutect2
- HROB | c.258G>A p.T86= | Silent (SNP) | VAF 97/593 reads (16%) | catalogued as rs747661873; called by muse, mutect2, varscan2
- HTRA3 | c.621G>A p.V207= | Silent (SNP) | VAF 27/776 reads (3%) | called by muse, mutect2
- IDUA | c.1911G>A p.P637= | Silent (SNP) | VAF 76/700 reads (11%) | catalogued as rs780005721, COSV99925588; called by muse, mutect2, varscan2
- KRT32 | c.331C>T p.L111= | Silent (SNP) | VAF 16/510 reads (3%) | called by muse, mutect2
- LYRM1 | c.175C>T p.L59= | Silent (SNP) | VAF 26/320 reads (8%) | called by muse, mutect2
- MTTP | c.1920T>C p.S640= | Silent (SNP) | VAF 93/287 reads (32%) | called by muse, mutect2, varscan2
- MUC16 | c.2970T>G p.T990= | Silent (SNP) | VAF 50/531 reads (9%) | catalogued as COSV67465919; called by muse, mutect2
- MYBPC2 | c.1527G>A p.T509= | Silent (SNP) | VAF 161/635 reads (25%) | catalogued as rs200711489; called by muse, mutect2, varscan2
- PGM5 | c.645T>A p.G215= | Silent (SNP) | VAF 48/324 reads (15%) | called by muse, varscan2
- PMIS2 | c.42C>T p.N14= | Silent (SNP) | VAF 242/625 reads (39%) | catalogued as rs553780461; called by muse, mutect2
- PON3 | c.628A>C p.R210= | Silent (SNP) | VAF 49/520 reads (9%) | called by muse, mutect2
- SDK2 | c.6285G>A p.S2095= | Silent (SNP) | VAF 34/584 reads (6%) | catalogued as rs757559673; called by muse, mutect2
- TRMT44 | c.273C>A p.P91= | Silent (SNP) | VAF 42/854 reads (5%) | called by muse, mutect2
- TSC22D4 | c.1140G>A p.S380= | Silent (SNP) | VAF 328/1061 reads (31%) | catalogued as rs372880072; called by muse, mutect2, varscan2
- ZNF558 | c.969C>T p.N323= | Silent (SNP) | VAF 137/484 reads (28%) | catalogued as rs73491457; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825497 C>G | 5'Flank (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- NBPF9 | c.2476+1594G>T | Intron (SNP) | VAF 62/342 reads (18%) | called by muse, mutect2, varscan2
